Surgical pathology report (de-identified scan), TCGA case TCGA-BS-A0TJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii, specimen TCGA-BS-A0TJ-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Patient Name: [REDACTED]
Med Rec No: [REDACTED] Client: [REDACTED]
DOB: [REDACTED] Location: [REDACTED]
Gender: F Pt. Phone no: [REDACTED]
Physician(s): [REDACTED]
cc: [REDACTED]

Accession #:
Taken:
Received:
Reported:

History/Clinical Dx: Adenocarcinoma of the uterus

Postoperative Dx: Pending pathology examination

10A-0-3

Specimen(s) Received:

A: Uterus, cervix, tubes and ovaries
B: Left pelvic lymph node
C: Left aortic lymph node
D: Right pelvic lymph node
E: Right caval lymph node

adenocarcinoma, endometrioid, nos 8380/3

Sitz: Indometrin C54.1

11/22/01 msh

DIAGNOSIS:

A. Uterus, cervix, tubes and ovaries:

ENDOMETRIAL ADENOCARCINOMA

Tumor Information:

Operative procedure:
Histologic type:
Histologic grade(FIGO):
Nuclear grade:
Tumor size:
Extent of invasion:

TAH-BSO with staging
Endometrioid with squamous differentiation *ok/lw*
Grade 3
2
3.8 cm
Greater than 50% of myometrial thickness (15mm invasion,
myometrial thickness of 26mm)

Lympho/vascular invasion:

Present

Serosa:

Free of tumor

Parametrium:

Free of tumor

Cervical involvement:

Absent

Right adnexa:

Free of tumor

Left adnexa:

Free of tumor

Other findings:

Adenomyosis

Special studies:

On request

Staging information:

T1c, NO

B. Left pelvic lymph nodes:

Fifteen lymph nodes negative for metastasis (0/15)

C. Left aortic lymph nodes:

Two lymph nodes negative for metastasis (0/2)

D. Right pelvic lymph nodes:

Nineteen lymph nodes negative for metastasis (0/19)

1. Performance Review
The performance review is a key tool for managers to assess the performance of their subordinates. It is a process by which managers evaluate the performance of their subordinates against a set of predetermined standards. The performance review is used for a variety of purposes, including to provide feedback to the employee, to identify areas for improvement, and to determine the employee's eligibility for a raise or promotion. The performance review is also used to document the employee's performance for future reference.

[page 2 of 3]
Surgical Pathology Report

E. Right caval lymph nodes:

Seven lymph nodes negative for metastasis (0/7)

Gross Description

A. Received: In formalin is a single piece of previously opened unoriented soft tan tissue

Labeled: "uterus, cervix, bilateral fallopian tubes and ovaries"

Weight: 160.0 gms

Size:

Uterus: 10.7 x 5.9 x 4.5 cm

Right ovary: 2.7 x 1.5 x 1.4 cm

Left ovary: 2.3 x 2.1 x 1.4 cm

Appearance

Tumor

Location: Circumferential, body of uterus

Configuration: Tan, friable, fungating

Size: 3.8 x 2.6 x 1.5 cm

Depth of invasion: Superficial, with <1/2 of involvement of the myometrium

Invasion of contiguous structures: None grossly identified

Distance from margins: 4.3 cm from the cervical margin

Cervix: Smooth, shiny, white with no lesions

Endometrium: 0.2 cm, smooth, shiny

Myometrium: 2.6 cm, with no areas of adenomyosis

Right tube and ovary (black): The right tube measures 4.2 x 0.4 x 0.4 cm, and is grossly unremarkable, with paratubal cystic structures. The cut surface of the ovary is homogeneous, tan to white, with no cystic structures.

Left tube and ovary: The left tube measures 4.6 x 0.5 x 0.4 cm, and is grossly unremarkable, with no paratubal cystic structures. The cut surface of the ovary is homogeneous, tan to white with no lesions. The left adnexa is inked blue.

Lymph nodes: None grossly identified

Special studies: Pending

Other: Multiple well-circumscribed, white with whorled cut surfaces myomas, largest up to 1.0 x 1.0 x 0.9 cm.

KEY TO CASSETTES:

- A1 - Cervix
- A2 - Lower uterine segment, full-thickness
- A3-A10 - Tumor and underlying myometrium
- A11 - Right parametrium (black)
- A12 - Left parametrium (blue)
- A13 - Right adnexa (black)
- A14 - Left adnexa (blue)

- B. Received in formalin labeled "left pelvic lymph node" are multiple fragments of soft tan to yellow tissue, 15.0 gms, aggregating up to 4.8 x 4.0 x 1.6 cm. There are 12 lymph nodes identified, largest up to 2.3 x 1.0 x 0.4 cm (inked black). Submitted in toto in six cassettes, with largest lymph node (black) in B1. Five lymph nodes in B2. Five lymph node in B3. One lymph node (yellow) in B4. Rest of specimen in B5 and B6.
- C. Received in formalin labeled "left aortic lymph nodes" are multiple fragments of soft tan yellow tissue, 2.0 gms, aggregating up to 2.0 x 1.5 x 0.3 cm. There are two lymph nodes, largest up to 1.4 x 0.6 x 0.3 cm (blue). Submitted in toto in one cassette.
- D. Received in formalin labeled "right pelvic lymph node" are multiple pieces of soft tan to yellow tissue, 22.0 gms, aggregating up to 5.8 x 5.3 x 2.4 cm. There are 13 lymph nodes, largest up to 2.5 x 0.6 x 0.3 cm (blue). Submitted in toto in five cassettes, with five lymph nodes in D1. Five lymph nodes in D2. Three lymph nodes in D3 (largest inked blue). Rest of specimen in D4 and D5.
- E. Received in formalin labeled "right caval lymph node" are four fragments of soft tan yellow tissue, 3.0 gms, aggregating up to 2.6 x 2.5 x 1.3 cm. There are seven lymph nodes, largest up to 1.4 x 0.5 x 0.3 cm (inked blue). Submitted in toto in two cassettes, with five lymph nodes in E1. And rest of specimen in E2 (largest lymph node inked blue).

[page 3 of 3]
Surgical Pathology Report

Microscopic Description

The microscopic findings support the above diagnosis.

Source: NCI Genomic Data Commons file bbde4c19-0568-4c7a-8ae1-a42c1f062f69 (TCGA-BS-A0TJ.17D921D9-F2ED-4F8E-8C6F-729C9A0FE5B0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).